Gene-level copy-number profile of tumor specimen TCGA-K1-A42W-01A from TCGA case TCGA-K1-A42W, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 65.5 years (23,910 days).
Specimen TCGA-K1-A42W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.db9a3940-19be-4c9e-bc2f-1daf319b024d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K1-A42W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9dde3775-bf11-447a-bfa6-6a986c66f927

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,664; copy number 2: 23,245; copy number 3: 21,876; copy number 4: 6,847; copy number 5: 4,039; copy number 6: 637; copy number 7: 454; copy number 8: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K1-A42W-01A-11D-A24M-01): tumor purity 0.71, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,005 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–218,345,678, 1,881 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–181,342,213, 2,985 genes, copy number 5–8 (broad region; genes not listed).
- chr15:19,878,555–22,617,854, 139 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,221. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
